Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5587, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5587-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Left kidney (165 grams, 11.5 x 5.8 x 3.8 cm) with 8 cm of attached ureter and left periaortic lymph nodes.

DIAGNOSIS:

Kidney, left, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 5.5 x 3.8 x 3.7 cm mass located in the inferior pole. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 6 cm in greatest linear extent. The tumor does not involve the collecting system. Sarcomatoid differentiation is absent. Coagulative tumor necrosis is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, left periaortic, excision: Multiple (8) left periaortic lymph nodes are negative for tumor.

[page 2 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Left kidney (165 grams, 11.5 x 5.8 x 3.8 cm) with 8 cm of attached ureter and left periaortic lymph nodes.

DIAGNOSIS:

Kidney, left, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 5.5 x 3.8 x 3.7 cm mass located in the inferior pole. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 6 cm in greatest linear extent. The tumor does not involve the collecting system. Sarcomatoid differentiation is absent. Coagulative tumor necrosis is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, left periaortic, excision: Multiple (8) left periaortic lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file da2e98be-c2ac-431c-85ea-3eecc2d45093 (TCGA-CW-5587.06D03BAF-182A-483E-B969-317A2A3CCED6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).